Gene-level copy-number profile of tumor specimen TCGA-30-1861-01A from TCGA case TCGA-30-1861, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.2 years (27,103 days).
Specimen TCGA-30-1861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4ae6e2e6-c949-4bd2-8258-156075a41920.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1861-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/99bd8596-189a-4e6e-96a4-bacd741cce1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,365; copy number 2: 23,435; copy number 3: 17,904; copy number 4: 6,826; copy number 5: 4,556; copy number 6: 2,014; copy number 7: 714; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-30-1861-01): tumor purity 0.72, ploidy 2.86, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,288 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,264,269–9,729,114, 90 genes, copy number 6 (broad region; genes not listed).
- chr1:35,268,709–40,692,066, 173 genes, copy number 5 (broad region; genes not listed).
- chr1:192,167,786–192,957,713, 1 gene, copy number 5 (within-gene range 4–5): AL390957.1.
- chr1:192,316,992–194,198,708, 26 genes, copy number 5 (within-gene range 4–5): RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL138778.1, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14.
- chr3:11,745–49,029,706, 819 genes, copy number 6–9 (broad region; genes not listed).
- chr3:163,455,568–168,095,924, 42 genes, copy number 6: AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1.
- chr3:168,288,553–168,291,228, 1 gene, copy number 6: AC124893.1.
- chr3:178,164,008–190,412,138, 255 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:18,418,662–18,888,662, 2 genes, copy number 5: AC093898.1, AC093871.1.
- chr4:148,078,762–155,953,910, 140 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:37,091,314–46,491,972, 226 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:8,938,787–33,109,404, 383 genes, copy number 5–7 (broad region; genes not listed).
- chr7:33,128,988–33,380,886, 4 genes, copy number 5: AC074338.1, RNA5SP229, AC007312.1, AC006195.1.
- chr7:101,239,458–131,110,176, 498 genes, copy number 5 (broad region; genes not listed).
- chr7:147,080,934–147,704,575, 6 genes, copy number 5: CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2.
- chr7:151,556,124–157,527,325, 99 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:157,574,336–157,869,154, 5 genes, copy number 5: MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2.
- chr8:78,626,775–89,415,071, 163 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:101,686,542–102,124,907, 1 gene, copy number 5 (within-gene range 4–5): NCALD.
- chr8:101,871,830–145,066,685, 652 genes, copy number 5–7 (broad region; genes not listed).
- chr10:44,712–29,736,959, 507 genes, copy number 5–6 (broad region; genes not listed).
- chr10:73,995,193–93,529,092, 361 genes, copy number 5–6 (broad region; genes not listed).
- chr11:90,251,204–90,915,052, 1 gene, copy number 5 (within-gene range 4–5): DISC1FP1.
- chr11:90,731,110–92,336,496, 16 genes, copy number 5: AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1.
- chr11:92,366,496–92,498,935, 3 genes, copy number 5: PGAM1P9, AP000722.1, RPS3AP42.
- chr12:25,874,020–34,249,958, 182 genes, copy number 5 (broad region; genes not listed).
- chr15:69,462,921–101,933,350, 850 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:35,928,570–45,410,610, 214 genes, copy number 5 (broad region; genes not listed).
- chr20:45,425,510–45,425,573, 1 gene, copy number 5: MIR6812.
- chr20:46,540,946–64,313,132, 426 genes, copy number 5–6 (broad region; genes not listed).
- chr21:23,065,491–33,977,691, 225 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:15,290,718–36,819,736, 916 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,365. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
